CCDI case PBCGKW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/f0d1a282-4a89-4250-8137-389e39213879

Demographics
Sex at birth: male.

Diagnoses (1)
1. Ganglioglioma, NOS: ICD-O-3 morphology code: 9505/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.4 years (4,163 days).

Biospecimens (3 samples)
- Sample 0DRE0L: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DRE0T: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DRE11: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
